FM case AD14753 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/5db2fdeb-95bd-4860-9d60-ff7074febc79

Male, 61.7 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
